TCGA case TCGA-GS-A9TQ — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: Fundacio Clinic per a la Recerca Biomedica. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/45b0cf9f-a879-417f-8f39-7770552252c0

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: Spain; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: primary; Age at diagnosis: 69.2 years (25,292 days); Year of diagnosis: 2012; AJCC staging edition: 7th; Ann Arbor clinical stage: Stage II; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 982 days (2.7 years); Ann Arbor extranodal involvement: No; Max tumor bulk site: Inguinal; Sites of involvement: Lymph Node, Femoral / Lymph Node, Inguinal.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes; Greatest tumor dimension: 3 cm; Measurement unit: Centimeters.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP-21; Days to treatment start: 24 days; Days to treatment end: 129 days; Number of cycles: 6.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.

Follow-up (6 entries)
- Days to follow up: 576 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 831 days (2.3 years); Disease response: Tumor Free.
- Days to follow up: 861 days (2.4 years); Disease response: Tumor Free.
- Days to follow up: 982 days (2.7 years); Disease response: Tumor Free.
- ECOG performance status: 1.
- Imaging type: PET; Imaging result: Negative; Timepoint: Within 2 Months After Completion of First-Course Treatment.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive.
- CD10 (IHC): Positive.
- CD138 (Flow Cytometry): Negative.
- CD19 (Flow Cytometry): Positive.
- CD20 (IHC): Positive.
- CD22 (Flow Cytometry): Positive.
- CD23 (Flow Cytometry): Positive.
- CD5 (Flow Cytometry): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Negative.
- Immunoglobulin, Cytoplasmic (IHC): Equivocal.
- Immunoglobulin, Surface (Flow Cytometry): Positive.
- MYC gain (FISH): Positive.
- TP53 (IHC): Negative.
- Lactate Dehydrogenase 364 IU [Blood test normal range upper: 450].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 68 kg; Height: 155 cm; BMI: 28.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GS-A9TQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-GS-A9TQ-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 10.
- Sample TCGA-GS-A9TQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GS-A9TQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 0; Bone marrow biopsy performed: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Femoral.
- Tests performed: LDH level: 364; Mib 1 positive percent range: 76 - 100%.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: CD138.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: CD22.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunopheotypic analysis tested: CD23.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunopheotypic analysis tested: CD79a; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunopheotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunopheotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunopheotypic analysis tested: P53 >20%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 12: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 13: Immunopheotypic analysis tested: Cytoplasmic Ig; Immunophenotypic analysis method: Immunohistochemistry; Immunopheotypic analysis results: Indeterminate.
- Tests performed, Genetic testing results, Genetic testing result 14: Immunopheotypic analysis tested: Surface Ig.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc; Genetic abnormality results: Gain.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 1, New tumor event: Treatment outcome at TCGA followup: Complete Remission/Response.
- Drug treatment 1: Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 2: Pharmaceutical therapy drug name: vincristina; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 3: Pharmaceutical therapy drug name: doxorubicina; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 4: Pharmaceutical therapy drug name: prednisona; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 5: Pharmaceutical therapy drug name: ciclofosfamida; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 982 days; disease-specific survival: no event (censored), 982 days; disease-free interval: no event (censored), 982 days; progression-free interval: no event (censored), 982 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GS-A9TQ-01A-11D-A381-01): tumor purity 0.74, ploidy 3.92, whole-genome doublings 2.
